HCMI case HCM-EXPT-0998-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/01f8a139-a027-4578-8cc0-3d931743f8d5

Demographics
Sex at birth: female; Year of birth: 1955.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,209 days); Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0998-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0998-C25-06A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
  Slide HCM-EXPT-0998-C25-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
